Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JI, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JI-01A (Primary Tumor).

Requesting Doctor's Information:

Carcinoma, adrenal cortical
8370/3
Site: ② Adrenal Gland, cortex
074.0
920 1/30/13

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:

Right adrenal gland. Lap Rt adrenalectomy -> incidentally found complex Rt adrenal lesion.

MACROSCOPIC:

'Right adrenal gland'. The specimen consists of an adrenal gland 70 x 45 x 40mm weighing 26g with scanty attached fatty tissue up to 5mm wide. One surface of the adrenal capsule is disrupted. On sectioning a yellow lobulated nodule 40 x 30 x 30mm with central cystic change and haemorrhage is present within the adrenal gland. The surrounding adrenal gland shows normal cortex and medulla. The nodule appears encapsulated by a fine capsule with no invasion into adjacent fat.

Block 1: adjacent normal adrenal gland

Blocks 2 to 6: representative nodule

Blocks 6 to 11:

MICROSCOPIC:

The 40 mm adrenal lesion is a low grade adrenal cortical carcinoma. It fulfils 3 of the Weiss criteria of malignancy (predominantly eosinophilic cell type, cytological atypia, diffuse architecture). The tumour is confined to the adrenal and separated from the soft tissue margin but an intact pseudocapsule indicating that local excision is complete. The mitotic rate is low (less than 1 mitosis per 10 hpf). No atypical mitoses are identified. There is no coagulative necrosis. There is no vascular or sinusoidal invasion. Numerous eosinophilic cytoplasmic globules (a feature associated with malignancy) are present. There is some myxoid change.

Immunohistochemistry supports the diagnosis of carcinoma and confirms adrenal cortical origin. It is as follows:

IGF2: Diffusely strongly positive with perinuclear dot-like staining

Ki-67: Low proliferative index (4%)

Calretinin: Positive

MelanA: Positive

S-100: Negative

Chromogranin: Negative

SUMMARY:

Right adrenal gland: Low grade adrenal cortical carcinoma 40 mm

NIHAA Discrepancy		
Case is (circled):	QUANTIFIED	DEQUANTIFIED

PATHOLOGY

ANATOMICAL PATHOLOGY

Source: NCI Genomic Data Commons file a459dce9-3de4-4231-8e35-059af00b28c1 (TCGA-OR-A5JI.F18AFE4B-5333-418A-A6D0-E347ACA3C06B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).